Somatic mutation profile of tumor specimen TCGA-EL-A3T1-01A (aliquot TCGA-EL-A3T1-01A-11D-A22D-08) from TCGA case TCGA-EL-A3T1, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 38.4 years (14,025 days).
Specimen TCGA-EL-A3T1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 92eded45-6f63-4c6e-93e5-f700487d1229.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3T1-11A (Solid Tissue Normal), aliquot TCGA-EL-A3T1-11A-11D-A22D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a0a7f7a7-2b4c-4d33-ad41-e4d8dbe929c2

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CFAP44 | c.2270C>T p.S757L | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.941); catalogued as COSV55614346; called by muse, mutect2, varscan2
- CUX1 | c.3193G>T p.E1065* | Nonsense Mutation (SNP) | VAF 38/270 reads (14%) | catalogued as COSV52918031; called by muse, mutect2, varscan2
- FH | c.1128G>T p.Q376H | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1467002768, COSV63819115; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPRIN2 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs147795605; called by muse, mutect2, varscan2
- MUC16 | c.29890G>A p.G9964R | Missense Mutation (SNP) | VAF 18/392 reads (5%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.378); catalogued as COSV67448815; called by muse, mutect2
- ROS1 | c.3059C>A p.P1020H | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100877845, COSV63862424; called by muse, mutect2, varscan2
- ZNF292 | c.1399G>T p.V467L | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1476687693, COSV60547822; called by muse, mutect2, varscan2
- TERT | c.3337del p.T1113Lfs*62 | Frame Shift Del (DEL) | VAF 6/41 reads (15%) | called by mutect2, pindel, varscan2
- DYRK1B | c.609C>T p.N203= | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as COSV59915616; called by muse, mutect2
- RPL23 | c.45G>C p.R15= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV55560726; called by muse, mutect2, varscan2
